Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5332, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5332-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Nck: contents right neck
2. Neck: Contents left neck
3. Soft Tissue: Left lateral margin - [REDACTED]
4. Soft Tissue: Right lateral margin - [REDACTED]
5. Soft Tissue: Cheek margin - [REDACTED]
6. Oral Cavity: Floor of mouth/gingiva oral cavity tumor - long stitch anterior, short posterior
7. Lymph node: Left external jugular vein lymph node
8. Surgical Waste
9. Soft Tissue: Revised cheek margin, stitch deep margin
10. Soft Tissue: Revised cheek margin - [REDACTED]

Diagnosis

1. Right neck contents.
Thirteen lymph nodes negative for tumor (0/13).
Submandibular gland with no pathologic changes.
2. Left neck contents.
Eighteen lymph nodes negative for tumor (0/18).
Submandibular gland with moderate chronic inflammation and partial atrophy.
3. Left lateral margin.
Negative for tumor.
4. Right lateral margin.
Negative for tumor.
5. Cheek margin.
Positive for carcinoma in situ.
6. Oral cavity; floor of mouth/gingiva oral cavity.
Squamous cell carcinoma, moderately differentiated.
- a. Largest tumor dimension 4.9 cm.
- b. Tumor thickness 4.5 cm.
- c. No perineural invasion.
- d. No lymphovascular invasion.
- e. The posterior and deep margins are close (<0.1 cm each) to tumor. All remaining margins, including bone margins, are negative for tumor.
-

[page 2 of 4]
7. Left external jugular vein lymph node.
One lymph node negative for tumor (0/1).

8. Surgical waste.
Skeletal muscle with no pathologic changes. (Gross examination only)

9. Revised cheek margin.
Negative for tumor.

10. Revised cheek margin.
Negative for tumor.

Synoptic Data

Specimen Type:	Resection: Left floor of mouth
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 4.9 cm Tumor thickness: 4.5 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	Carcinoma in situ Inflammation (type): (Left parotid gland)
Margins:	Margins uninvolved by tumor Margins uninvolved by tumor - Distance of tumor from closest margin: 0.1 cm Margins: posterior and deep
Pathologic Staging (pTNM):	pT3: Tumor of lip or oral cavity more than 4 cm in greatest dimension pN0: No regional lymph node metastasis for aerodigestive sites Number of regional lymph nodes examined: 31 Number of regional lymph nodes involved: 0 pMX: Distant metastasis cannot be assessed

Clinical History

oral ca

Gross Description

1. The specimen is labeled with the patient's name and "contents right neck". It consists of an oriented left neck dissection with overall dimensions of 13 x 8 x 1.4 cm. No internal jugular vein seen. The sternocleidomastoid is unremarkable and measures 2.7 x 1.5 x 1.0 cm. The submandibular gland measures 4.7 x 2.5 x 1.4 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1.7 x 0.8 x 0.6 cm are identified in multiple levels. Representative sections are submitted.

1A submandibular gland
1B level I one lymph node
1C level I, multiple lymph nodes
1D level I, one lymph node
1E level II two lymph nodes
1F level III multiple lymph nodes
1G level III multiple lymph nodes
1H-1I level III one lymph node

[page 3 of 4]
2. The specimen is labeled with the patient's name and "contents left neck". It consists of an oriented left neck dissection with overall dimensions of 12 x 7 x 2.0 cm. The internal jugular vein measures 1 x 0.4 cm in length and is otherwise unremarkable. The sternocleidomastoid is unremarkable and measures 4 x 1.5 x 0.7 cm. The submandibular gland measures 3 x 2.5 x 1.8 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1.6 x 1 x 0.4 cm are identified in multiple levels. Representative sections are submitted.

- 2A submandibular gland
- 2B level I multiple lymph nodes
- 2C level I one lymph node
- 2D level II multiple lymph nodes
- 2E level II one lymph node
- 2F level II two lymph nodes
- 2G level III multiple lymph nodes
- 2H level III one lymph node

3. The specimen is labeled with the patient's name and "left lateral margin". It consists of a fragment of tissue measuring 0.4 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

- 3A frozen section control

4. The specimen is labeled with the patient's name and "right lateral margin". It consists of a fragment of tissue measuring 0.4 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

- 4A frozen section control

5. The specimen is labeled with the patient's name and "cheek margin". It consists of a fragment of tissue measuring 1.5 x 0.5 x 0.3 cm. The specimen is submitted in toto for frozen section.

- 5A frozen section control

6. The specimen is labeled with the patient's name and "floor of mouth/gingiva oral cavity tumor-long stitch anterior short posterior". It consists of a left floor of mouth with left marginal mandible measuring 6.5 AP x 4.2 SI x 4.0 ML cm. It includes a portion of mandible with no teeth. There is a tumor arising in floor of mouth. The tumor measures 4.9 AP x 4.5 SI x 3.5 ML cm. The tumor is ulcerated. There is no gross involvement of bone by the tumour. The tumor is located at 0.1 cm from the closest lateral gingival margin, 0.1cm posterior floor of mouth margin, 0.1 cm deep inferior margin, 0.1 cm medial margin. Remaining margins are as follows: 0.8 anterior floor of mouth mucosal margin and 0.5 medial floor of mouth margin. Representative sections are submitted.

- 6A anterior floor of mouth margin
- 6B posterior floor of mouth margin
- 6C lateral gingiva margin
- 6D medial floor small to margin
- 6E inferior/deep soft tissue margin
- 6F medial soft tissue margin
- 6G-6I tumor
- 6J anterior mandible margin
- 6K posterior mandible margin
- 6L-6M mandible and tumor

7. The specimen is labeled with the patient's name and "left external jugular vein lymph node". It consists of one lymph node measuring 1 x 0.4 x 0.4 cm.

- 7A specimen in toto

8. The specimen is labeled with the patient's name and "surgical waste". It consists of a portion of grossly unremarkable skeletal muscle measuring 3 x 2 x 1.0 cm. No sections are submitted for microscopic examination.

9. The specimen is labeled with the patient's name and "revised cheek margin stitch deep margin". It consists of a portion of soft tissue measuring 3.5 x 1 x 0.5 cm. The sutured surface is painted with India ink and the specimen serially sectioned.

- 9A-9C specimen in toto

10. The specimen is labeled with the patient's name and "revised cheek margin". It consists of a fragment of tissue measuring 0.6 x 0.5 x 0.2 cm. The specimen is submitted in toto for frozen section.

[page 4 of 4]
[REDACTED]

10A frozen section control

[REDACTED]

Quick Section Diagnosis

3A-4A: Left lateral and right lateral margins; negative for malignancy.

5A: Cheek margin: positive for carcinoma in-situ, at least.

Called at 2:10 PM.

10A: Revised cheek margin; negative for malignancy. [REDACTED]

Source: NCI Genomic Data Commons file db354911-d32d-4f82-9200-eb486b119768 (TCGA-CQ-5332.FF1DC654-3589-40A3-9851-DA2472643849.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).